Gene-level copy-number profile of tumor specimen TCGA-A2-A0CU-01A from TCGA case TCGA-A2-A0CU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.4 years (26,823 days).
Specimen TCGA-A2-A0CU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.846ab0bd-1c82-48a3-a25a-8a3af1f2bfa0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0CU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0fefa9d5-6d2e-48d3-a468-97bb8e17452d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 1,172; copy number 2: 16,127; copy number 3: 26,289; copy number 4: 13,071; copy number 5: 1,269; copy number 6: 1,074; copy number 7: 655; copy number 8: 1; copy number 9: 139.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0CU-01A-12D-A036-01): tumor purity 0.57, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:26,519,354–26,782,104, 11 genes (within-gene range 0–2): DPPA2P2, RPS6KA1, MIR1976, RN7SL679P, Y_RNA, RNU7-29P, AL627313.1, AL627082.2, AL627082.1, AL512408.1, ARID1A.
- chr17:12,020,829–12,143,830, 1 gene (within-gene range 0–1): MAP2K4.
- chr17:12,081,899–12,115,885, 2 genes: MIR744, AC005244.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 795 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:9,741,672–13,705,506, 137 genes, copy number 8–9 (within-gene range 2–9) (broad region; genes not listed).
- chr8:36,378,069–36,779,209, 3 genes, copy number 9 (within-gene range 2–9): AC090809.1, RPL23P10, RNA5SP264.
- chr8:101,686,542–145,066,685, 655 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,172. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
